Somatic mutation profile of cancer-model specimen HCM-CSHL-0853-C56-85G (3D Organoid, passage 7; aliquot HCM-CSHL-0853-C56-85G-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-85G: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe3c68cd-efdb-4ab5-b168-79542d700dbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0853-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0853-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2aeeb68-49b7-4b37-8ed7-566017cd1612

The open-access MAF lists 48 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Frame Shift Del 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 168/170 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.2671G>T p.G891W | Missense Mutation (SNP) | VAF 23/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99547047; called by muse, mutect2
- ARHGEF40 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs140826804; called by muse, mutect2, varscan2
- CFAP47 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 223/225 reads (99%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs760933446, COSV52884417; called by muse, mutect2, varscan2
- CTNNA2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 127/272 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV58173470; called by muse, mutect2, varscan2
- FAM160A2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 219/406 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768160220; called by muse, mutect2, varscan2
- FLT3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 189/374 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201208287, COSV54046882, COSV54065904; called by muse, mutect2, varscan2
- KLF15 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 143/669 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1460973278; called by muse, mutect2, varscan2
- MUC12 | c.5341A>G p.S1781G (on ENST00000379442; = p.S1638G on NM_001164462.1) | Missense Mutation (SNP) | VAF 254/632 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs75280441; called by mutect2, varscan2
- OR5R1 | c.567C>G p.C189W | Missense Mutation (SNP) | VAF 222/437 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100393585; called by muse, mutect2, varscan2
- PPFIA4 | c.2323G>C p.D775H (on ENST00000447715; = p.D776H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 232/486 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs774650502; called by muse, mutect2, varscan2
- PRKD1 | c.503G>C p.W168S | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV59571208; called by muse, mutect2
- SMAD9 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 48/860 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375480745; called by muse, mutect2
- TMEM52B | c.201C>G p.C67W (on ENST00000381923 / NM_001079815.1; = p.C47W on NM_153022.4) | Missense Mutation (SNP) | VAF 158/461 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53727720; called by muse, mutect2, varscan2
- TRHDE | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 237/522 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1445798045; called by muse, mutect2, varscan2
- UGT2B28 | c.1088T>C p.L363P | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396247888, COSV59432262; called by muse, mutect2, varscan2
- ACE | c.2223_2225del p.N741del | In Frame Del (DEL) | VAF 264/278 reads (95%) | called by pindel, varscan2
- AMPH | c.74T>A p.L25H | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPT2 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 175/549 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L4B | c.2068G>T p.D690Y | Missense Mutation (SNP) | VAF 137/399 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- FRRS1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- GRSF1 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ITIH4 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 146/148 reads (99%) | SIFT tolerated (0.19); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- LRRK2 | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 214/342 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NMU | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PACS1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 151/734 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); called by muse, varscan2
- PKD1 | c.6334_6347del p.H2112Afs*58 | Frame Shift Del (DEL) | VAF 106/419 reads (25%) | called by mutect2, pindel, varscan2
- PRSS36 | c.2477G>A p.S826N | Missense Mutation (SNP) | VAF 340/342 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SGPL1 | c.876_877del p.H292Qfs*8 | Frame Shift Del (DEL) | VAF 204/555 reads (37%) | called by mutect2, pindel, varscan2
- SLC6A3 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 175/610 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- SPATA18 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 179/388 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SPATS2L | c.181A>G p.M61V | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- SYT4 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 75/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAF5L | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 22/656 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2
- TRPA1 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM20 | c.507A>C p.P169= | Silent (SNP) | VAF 171/316 reads (54%) | called by muse, mutect2, varscan2
- AP3B1 | c.1932C>T p.P644= | Silent (SNP) | VAF 102/103 reads (99%) | catalogued as rs368771979; called by muse, mutect2, varscan2
- BABAM2 | c.1125G>A p.E375= | Silent (SNP) | VAF 199/387 reads (51%) | called by muse, mutect2, varscan2
- COL22A1 | c.588C>T p.H196= | Silent (SNP) | VAF 87/1752 reads (5%) | catalogued as rs1167546280, COSV57346244; called by muse, mutect2
- KIAA1522 | c.777C>A p.T259= (on ENST00000373480 / NM_001198972.2; = p.T318= on NM_020888.3) | Silent (SNP) | VAF 658/1026 reads (64%) | called by muse, mutect2, varscan2
- KLHDC7B | c.1744C>T p.L582= (on ENST00000395676; = p.L1223= on NM_138433.5) | Silent (SNP) | VAF 257/355 reads (72%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.867C>T p.N289= | Silent (SNP) | VAF 376/377 reads (100%) | catalogued as rs374654639; called by muse, mutect2, varscan2
- MUC12 | c.2910T>C p.H970= (on ENST00000379442; = p.H827= on NM_001164462.1) | Silent (SNP) | VAF 188/468 reads (40%) | catalogued as rs1232372270; called by muse, varscan2
- NCAPH | c.687C>T p.N229= | Silent (SNP) | VAF 151/335 reads (45%) | catalogued as rs760742546; called by muse, mutect2, varscan2
- NLRP12 | c.1890G>C p.L630= | Silent (SNP) | VAF 11/344 reads (3%) | catalogued as COSV60754783; called by muse, mutect2
- RNF187 | c.426C>T p.D142= | Silent (SNP) | VAF 21/622 reads (3%) | called by muse, mutect2
- SLC6A12 | c.1554C>T p.S518= | Silent (SNP) | VAF 149/338 reads (44%) | called by muse, mutect2, varscan2
- HSPB7 | chr1:16019339 del CTGT | 5'Flank (DEL) | VAF 303/715 reads (42%) | called by mutect2, pindel, varscan2
